Somatic mutation profile of tumor specimen TCGA-B0-5696-01A (aliquot TCGA-B0-5696-01A-11D-1534-10) from TCGA case TCGA-B0-5696, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G4; Age at diagnosis: 70.0 years (25,552 days).
Specimen TCGA-B0-5696-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6656e423-6a4a-4635-b3c5-14f9b0ee1900.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5696-11A (Solid Tissue Normal), aliquot TCGA-B0-5696-11A-01D-1534-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db305935-b858-4c1d-9628-e484bbe4cad4

The open-access MAF lists 56 somatic variants for this specimen: 44 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 32, Silent 12, Frame Shift Del 3, Frame Shift Ins 3, Nonsense Mutation 3, Splice Site 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.4448G>A p.C1483Y | Missense Mutation (SNP) | VAF 23/100 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs786205165, CM1412980, CM153079, COSV63869079, COSV63869516; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC4 | c.941C>G p.S314C | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV65312080; called by muse, mutect2, varscan2
- ABL1 | c.225T>G p.S75R | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.665); catalogued as COSV59330319; called by muse, mutect2, varscan2
- ADGRF1 | c.96dup p.E33Rfs*6 | Frame Shift Ins (INS) | VAF 64/382 reads (17%) | catalogued as rs771491120; called by mutect2, varscan2
- AFDN | c.3745T>G p.W1249G | Missense Mutation (SNP) | VAF 62/252 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV60043368, COSV60051726; called by muse, mutect2, varscan2
- ALKBH6 | c.25C>A p.P9T (on ENST00000252984 / NM_001297701.2; = p.P37T on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV53324506; called by muse, mutect2, varscan2
- ALMS1 | c.1066T>A p.W356R | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV52508403; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3986T>G p.L1329R | Missense Mutation (SNP) | VAF 56/414 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51845705, COSV51860454; called by muse, mutect2
- ANO3 | c.992T>C p.I331T | Missense Mutation (SNP) | VAF 164/640 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as rs751447376, COSV56789413; called by muse, mutect2, varscan2
- ANPEP | c.847A>G p.I283V | Missense Mutation (SNP) | VAF 66/263 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.08); catalogued as COSV55591072; called by muse, mutect2
- BDP1 | c.7468A>C p.T2490P | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV62430921; called by muse, mutect2, varscan2
- C3 | c.754G>T p.E252* | Nonsense Mutation (SNP) | VAF 10/59 reads (17%) | catalogued as rs748526595, COSV55571959, COSV99836267; called by muse, mutect2, varscan2
- COL27A1 | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs781277879, COSV61925278; called by muse, mutect2
- CYP2A13 | c.1467G>T p.M489I | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.031); catalogued as COSV57836661, COSV57837396; called by muse, mutect2
- ELF2 | c.296C>T p.A99V (on ENST00000379550 / NM_001331036.2; = p.A39V on NM_006874.4) | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55492769; called by muse, mutect2
- FAM104A | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.937); catalogued as COSV55429315; called by muse, mutect2, varscan2
- FASN | c.5207C>T p.T1736M | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1408119005, COSV60753588; called by muse, mutect2, varscan2
- IL21R | c.632A>G p.Q211R | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV61969942; called by muse, mutect2
- ISOC1 | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 112/826 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV51491601; called by muse, mutect2, varscan2
- KANSL2 | c.638G>T p.R213L | Missense Mutation (SNP) | VAF 13/253 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100771065, COSV63479600; called by muse, mutect2
- LRRC57 | c.560G>T p.C187F | Missense Mutation (SNP) | VAF 28/315 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52999900; called by muse, mutect2
- MAN2A1 | c.1230G>C p.K410N | Missense Mutation (SNP) | VAF 79/356 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54850888, COSV99811912; called by muse, mutect2, varscan2
- MKI67 | c.3916G>T p.E1306* | Nonsense Mutation (SNP) | VAF 34/350 reads (10%) | catalogued as COSV64074085; called by muse, mutect2, varscan2
- MYO3A | c.1408G>T p.V470L | Missense Mutation (SNP) | VAF 26/340 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.107); catalogued as COSV56328322; called by muse, mutect2
- OR5J2 | c.728C>G p.S243C | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56620126, COSV56620982; called by muse, mutect2, varscan2
- PBRM1 | c.2495del p.N832Ifs*23 | Frame Shift Del (DEL) | VAF 85/282 reads (30%) | catalogued as COSV56295851; called by mutect2, pindel, varscan2
- PDE3A | c.2701G>T p.V901F | Missense Mutation (SNP) | VAF 148/447 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62971651; called by muse, mutect2, varscan2
- PPP1R9A | c.2491A>T p.N831Y | Missense Mutation (SNP) | VAF 84/372 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV56890446, COSV56893935; called by muse, mutect2, varscan2
- PRPS2 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.201); catalogued as COSV66126204; called by muse, mutect2
- RPTOR | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs148973724; called by muse, mutect2, varscan2
- RTTN | c.4438C>T p.L1480F | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773407722, COSV55343912; called by muse, mutect2, varscan2
- SHISA4 | c.547+1G>T p.X183_splice | Splice Site (SNP) | VAF 19/66 reads (29%) | catalogued as COSV62884501; called by muse, mutect2, varscan2
- SLITRK5 | c.1929G>T p.L643F | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV61522459; called by muse, mutect2, varscan2
- SPATA5 | c.1471G>T p.G491* | Nonsense Mutation (SNP) | VAF 18/76 reads (24%) | catalogued as COSV56775017; called by mutect2, varscan2
- TAZ | c.751C>G p.R251G | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as rs372689133, COSV54796296; called by muse, mutect2, varscan2
- TENM1 | c.1015+1G>T p.X339_splice | Splice Site (SNP) | VAF 29/67 reads (43%) | catalogued as COSV64430674; called by muse, mutect2, varscan2
- TEX45 | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs888792115, COSV64463084; called by muse, mutect2, varscan2
- UPF2 | c.2063T>C p.L688S | Missense Mutation (SNP) | VAF 110/448 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62660268; called by muse, mutect2, varscan2
- VHL | c.473dup p.K159Efs*15 | Frame Shift Ins (INS) | VAF 34/112 reads (30%) | catalogued as CI024083, CI962364, COSV56565013; called by mutect2, pindel, varscan2
- AC245033.1 | c.1595A>C p.N532T | Missense Mutation (SNP) | VAF 127/539 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- FCN3 | c.775_779del p.Y259Ifs*11 | Frame Shift Del (DEL) | VAF 15/60 reads (25%) | called by mutect2, pindel, varscan2
- GSTA4 | c.160_162del p.Q54del | In Frame Del (DEL) | VAF 52/232 reads (22%) | called by pindel, varscan2
- OTULINL | c.205del p.S69Qfs*5 | Frame Shift Del (DEL) | VAF 93/420 reads (22%) | called by mutect2, pindel*, varscan2
- SHANK3 | c.1910dup p.Q638Afs*55 | Frame Shift Ins (INS) | VAF 21/86 reads (24%) | called by mutect2, pindel, varscan2
- BICRAL | c.2865G>A p.L955= | Silent (SNP) | VAF 38/116 reads (33%) | catalogued as rs745559776, COSV58404988; called by muse, mutect2, varscan2
- CA6 | c.462T>C p.D154= | Silent (SNP) | VAF 71/275 reads (26%) | catalogued as COSV66262034; called by muse, mutect2, varscan2
- CUBN | c.7272T>C p.N2424= | Silent (SNP) | VAF 36/150 reads (24%) | catalogued as COSV64714229; called by muse, mutect2, varscan2
- FASTKD1 | c.1128A>G p.L376= | Silent (SNP) | VAF 139/579 reads (24%) | catalogued as COSV71624261; called by muse, mutect2, varscan2
- FBN2 | c.5151C>T p.C1717= | Silent (SNP) | VAF 24/260 reads (9%) | catalogued as COSV52508634, COSV52534269; called by muse, mutect2
- GAB4 | c.969A>T p.G323= | Silent (SNP) | VAF 38/144 reads (26%) | catalogued as COSV68753691; called by muse, varscan2
- LIMA1 | c.1905A>G p.Q635= | Silent (SNP) | VAF 87/396 reads (22%) | catalogued as COSV57965197; called by muse, mutect2, varscan2
- MLLT10 | c.2841A>C p.P947= (on ENST00000307729 / NM_001195626.3; = p.P963= on NM_004641.3) | Silent (SNP) | VAF 26/122 reads (21%) | catalogued as COSV56993358, COSV56994768; called by muse, mutect2
- NCOA6 | c.2460T>C p.D820= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV62863078; called by muse, mutect2
- PTPRZ1 | c.2586G>A p.V862= | Silent (SNP) | VAF 37/154 reads (24%) | catalogued as COSV66435297; called by muse, mutect2, varscan2
- SDK2 | c.2055C>A p.L685= | Silent (SNP) | VAF 30/110 reads (27%) | catalogued as COSV66185026; called by muse, mutect2, varscan2
- TSHZ3 | c.192C>T p.A64= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as rs375736734, COSV53675522; called by muse, mutect2, varscan2
